Surgical pathology report (de-identified scan), TCGA case TCGA-B3-8121, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B3-8121-01A (Primary Tumor).

[REDACTED]

Phon [REDACTED]

Final Surgical Pathology Report

Procedure: [REDACTED]

Diagnosis

- A. Right kidney, partial resection:
Papillary renal cell carcinoma, 2.7 cm, margins negative but close.
- B. Right kidney, deep margin, biopsy:
No carcinoma identified.

Microscopic Description:

Microscopic examination performed:

A.

Type: Papillary carcinoma
Histologic grade (Fuhrman Nuclear Grade: 3
Primary tumor (pT): 2.7 cm, pT1
Margins of resection: negative but close, < 1mm
Regional lymph nodes (pN): none submitted
Distant metastasis (pM): cannot be evaluated by this specimen
Vascular invasion: not identified
Non-neoplastic kidney: unremarkable
Other findings: none

B. Sections of the deep margin show no evidence of malignancy.

Specimen

- A. Right renal mass
- B. Right kidney, deep margin

Clinical Information

Right renal mass

Intraoperative Consultation

right kidney, deep margin, biopsy: No malignancy identified

[REDACTED]

Gross Description

- A. Received is a container labeled with the patient's name, medical record number and "right renal mass". The specimen consists of a circumscribed piece of tan-brown tissue measuring 2.8 x 3.1 x 2.5 cm. The surgical margin is inked black the specimen is serially sectioned. On the entire specimen is occupied by a circumscribed lesion which is yellow-brown and necrotic. A thin fibrous capsule and nests the cystic mass. The entire specimen is submitted in A1 to A5.
- B. Container B. is labeled with the patient's name, medical record number and "deep margin". The specimen consists of a single piece of tissue measuring 0.6-0.6 x 0.3 cm. All submitted in BFS.
- [REDACTED]
- [REDACTED]

Source: NCI Genomic Data Commons file bddfb571-3cd9-4756-bdfc-8a89caf494cd (TCGA-B3-8121.DEC64E5E-D4B2-44B8-9B60-ECE8C954F4CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).